Somatic mutation profile of tumor specimen TCGA-50-8459-01A (aliquot TCGA-50-8459-01A-11D-2323-08) from TCGA case TCGA-50-8459, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.1 years (24,859 days).
Specimen TCGA-50-8459-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6af1bbd2-79d9-4a1f-b527-ef6d0177e37c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-8459-10A (Blood Derived Normal), aliquot TCGA-50-8459-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8cfc1c7-eba1-44d1-824e-a64c61d071b5

The open-access MAF lists 90 somatic variants for this specimen: 62 protein-altering or splice-affecting, 24 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 24, Nonsense Mutation 6, Splice Site 2, 5'UTR 2, Frame Shift Del 1, Frame Shift Ins 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 19/28 reads (68%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PEX1 | c.2383C>T p.R795* | Nonsense Mutation (SNP) | VAF 26/200 reads (13%) | catalogued as rs61750418, CM991032, COSV99952132; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADM | c.530C>A p.P177Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.404); catalogued as COSV53402822, COSV99534241; called by muse, mutect2, varscan2
- AFAP1L1 | c.759C>A p.S253R | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV57048670; called by muse, mutect2, varscan2
- AHNAK2 | c.7757T>C p.L2586P | Missense Mutation (SNP) | VAF 44/273 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100317643; called by muse, mutect2, varscan2
- ARG1 | c.156C>A p.D52E | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as COSV99256122; called by muse, mutect2, varscan2
- C16orf78 | c.484C>G p.Q162E | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV100147759; called by muse, mutect2, varscan2
- C17orf97 | c.1175A>T p.Q392L | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs782427003, COSV100789351; called by muse, mutect2, varscan2
- C5orf24 | c.522T>G p.H174Q | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.6); catalogued as COSV100574521; called by muse, mutect2
- CHRND | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.089); catalogued as rs780882716, COSV99285559; called by muse, mutect2, varscan2
- CRB1 | c.1786C>A p.P596T | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.304); catalogued as COSV100957897, COSV66329881; called by muse, mutect2, varscan2
- CRB1 | c.1787C>A p.P596H | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV66332587; called by muse, mutect2, varscan2
- DCT | c.803A>G p.D268G | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.866); catalogued as rs1187769005, COSV100986225; called by muse, mutect2, varscan2
- DNAH11 | c.7913A>C p.Q2638P | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100179378; called by muse, mutect2
- EGF | c.1782G>C p.K594N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV99490310, COSV99490967, COSV99491498; called by muse, mutect2, varscan2
- ERBB4 | c.2717A>G p.Y906C | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100725993, COSV100726881; called by muse, mutect2, varscan2
- FREM2 | c.2326C>T p.Q776* | Nonsense Mutation (SNP) | VAF 5/59 reads (8%) | catalogued as COSV99748954; called by muse, mutect2
- GRB7 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1267029682, COSV100485522; called by muse, mutect2, varscan2
- HMGCLL1 | c.925G>A p.G309S | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99232286; called by muse, mutect2, varscan2
- IQGAP2 | c.1519G>T p.G507* | Nonsense Mutation (SNP) | VAF 9/85 reads (11%) | catalogued as COSV99167363; called by muse, mutect2, varscan2
- KHK | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs747346841, COSV99566235; called by muse, mutect2, varscan2
- KMT2D | c.13001C>A p.A4334D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV99982373; called by muse, mutect2, varscan2
- LAMA2 | c.1356C>A p.S452R | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV101370494; called by muse, mutect2, varscan2
- LGR5 | c.2192T>A p.L731* | Nonsense Mutation (SNP) | VAF 25/118 reads (21%) | catalogued as COSV99877968; called by muse, mutect2, varscan2
- LRRC71 | c.1061G>A p.S354N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as COSV100504007; called by muse, varscan2
- MAGED1 | c.2026G>T p.A676S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV100431614; called by muse, mutect2, varscan2
- MMP16 | c.1548G>C p.K516N | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV99688507; called by muse, mutect2, varscan2
- MYO16 | c.4057C>T p.R1353C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs905217566, COSV62749945, COSV62750295; called by muse, mutect2, varscan2
- NAALAD2 | c.1373C>G p.P458R | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753044181, COSV100428476; called by muse, mutect2
- NBEA | c.2702A>G p.Y901C | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1335616215, COSV59777033; called by muse, mutect2, varscan2
- NRXN1 | c.3461T>C p.I1154T | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV100455351; called by mutect2, varscan2
- OR13F1 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100594772; called by muse, mutect2, varscan2
- OR52E4 | c.754T>A p.F252I | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100389259; called by muse, mutect2, varscan2
- OR5AN1 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV100004351; called by muse, mutect2, varscan2
- OR5J2 | c.123G>T p.R41S | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100399047, COSV56623751; called by muse, mutect2, varscan2
- OR7D4 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs112089905, COSV58071510; called by muse, mutect2, varscan2
- PCDH17 | c.2119C>A p.P707T | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV100931686; called by muse, mutect2
- PCDHA3 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as COSV100793489; called by muse, mutect2
- PCDHA6 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.057); catalogued as COSV100971510; called by muse, mutect2
- PCDHB11 | c.1498C>A p.L500I | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV100697022; called by muse, mutect2, varscan2
- PDE6B | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.98); PolyPhen benign (0.036); catalogued as COSV99727630; called by muse, mutect2, varscan2
- PEG3 | c.2985G>T p.K995N | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.273); catalogued as COSV99689121; called by muse, mutect2, varscan2
- PTPRD | c.3760G>C p.D1254H | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as COSV100644911, COSV61933107; called by muse, mutect2, varscan2
- RASSF9 | c.537T>A p.D179E | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV100771394; called by muse, mutect2, varscan2
- RBBP7 | c.533A>G p.E178G | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as COSV101198288; called by muse, mutect2, varscan2
- REG3A | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100532737; called by muse, mutect2, varscan2
- RHOBTB1 | c.2064C>G p.F688L | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as COSV100558490; called by muse, mutect2, varscan2
- RIPPLY2 | c.213G>T p.K71N | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100860738; called by muse, mutect2, varscan2
- SI | c.2981G>T p.G994V | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100015692; called by muse, mutect2, varscan2
- SLC22A16 | c.1360A>G p.I454V | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.545); catalogued as COSV100397503; called by muse, mutect2, varscan2
- ST18 | c.1070-1G>C p.X357_splice | Splice Site (SNP) | VAF 19/142 reads (13%) | catalogued as COSV99389760; called by muse, mutect2, varscan2
- ST8SIA4 | c.716G>T p.W239L | Missense Mutation (SNP) | VAF 19/114 reads (17%) | PolyPhen benign (0.038); catalogued as COSV99185310; called by muse, mutect2, varscan2
- VMP1 | c.624G>T p.M208I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV99230482; called by muse, mutect2, varscan2
- ZC3H10 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.08); catalogued as COSV99230517; called by muse, mutect2, varscan2
- ZC3H12C | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs763939056, COSV99585029; called by muse, mutect2
- ZFHX4 | c.4782G>T p.K1594N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50659202; called by muse, mutect2, varscan2
- ZNF521 | c.1861C>T p.Q621* | Nonsense Mutation (SNP) | VAF 15/120 reads (13%) | catalogued as COSV64131487; called by muse, mutect2, varscan2
- ZNF567 | c.369C>A p.N123K (on ENST00000536254 / NM_001322913.1; = p.N92K on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1268456938, COSV100658819; called by muse, mutect2, varscan2
- KCNF1 | c.1263del p.A422Rfs*8 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- PKHD1 | c.11399-1G>T p.X3800_splice | Splice Site (SNP) | VAF 19/131 reads (15%) | called by muse, mutect2, varscan2
- RFC4 | c.958_961dup p.D321Vfs*2 | Nonsense Mutation (INS) | VAF 7/64 reads (11%) | called by mutect2, pindel
- TRAM1L1 | c.403dup p.W135Lfs*9 | Frame Shift Ins (INS) | VAF 14/110 reads (13%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.4020A>G p.L1340= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV99485319; called by muse, mutect2, varscan2
- AHCTF1 | c.6300A>T p.S2100= (on ENST00000366508; = p.S2074= on NM_015446.5) | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV100403785; called by muse, mutect2, varscan2
- ASB10 | c.690G>T p.L230= (on ENST00000420175 / NM_001142459.2; = p.L215= on NM_080871.4) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1367934690, COSV99318646; called by muse, mutect2, varscan2
- C2CD2 | c.1548A>T p.S516= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV100298182; called by muse, mutect2
- DHX16 | c.2883A>G p.T961= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs1196440303, COSV99527985; called by muse, mutect2, varscan2
- EP400 | c.3078G>T p.A1026= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV100201292; called by muse, mutect2, varscan2
- FANCM | c.306T>C p.A102= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV99360949; called by muse, mutect2, varscan2
- FGD5 | c.2248C>A p.R750= | Silent (SNP) | VAF 35/227 reads (15%) | catalogued as COSV99548181; called by muse, mutect2, varscan2
- FYB1 | c.513C>A p.P171= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as COSV100685480; called by muse, mutect2, varscan2
- GP5 | c.1434G>A p.P478= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs1209872580, COSV100540892, COSV59878937; called by mutect2, varscan2
- HERC4 | c.2556A>G p.P852= (on ENST00000395198 / NM_022079.3; = p.P844= on NM_015601.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV99517045; called by muse, mutect2, varscan2
- HEY2 | c.393A>G p.T131= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV100856387; called by muse, mutect2, varscan2
- HPX | c.414A>C p.G138= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV99793349; called by muse, mutect2, varscan2
- IGLV5-45 | c.126C>A p.T42= | Silent (SNP) | VAF 11/110 reads (10%) | called by muse, varscan2
- MC2R | c.795C>A p.I265= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV100563012; called by muse, mutect2, varscan2
- NDN | c.282C>G p.A94= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100086461; called by mutect2, varscan2
- PKDREJ | c.4593G>A p.P1531= | Silent (SNP) | VAF 46/276 reads (17%) | catalogued as rs371794261, COSV99478649; called by muse, mutect2, varscan2
- POLN | c.1480C>T p.L494= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV101242515; called by muse, mutect2, varscan2
- RASGRP2 | c.981C>G p.T327= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100818263; called by muse, mutect2, varscan2
- SAA2 | c.285G>T p.L95= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV99879343; called by muse, mutect2
- TMEM106B | c.654C>T p.S218= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV101188823; called by muse, mutect2, varscan2
- TPO | c.906C>G p.G302= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100219547, COSV100221191; called by muse, mutect2, varscan2
- TTC17 | c.441A>T p.T147= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV99235371; called by muse, mutect2, varscan2
- TYR | c.1458C>A p.A486= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV54480361; called by muse, mutect2, varscan2
- ANKRD33 | c.-270C>A | 5'UTR (SNP) | VAF 15/80 reads (19%) | catalogued as COSV100001329; called by muse, mutect2, varscan2
- ANKRD33 | c.-269C>A | 5'UTR (SNP) | VAF 14/79 reads (18%) | catalogued as COSV100001332; called by muse, mutect2, varscan2
- SEMA4G | c.336+1376G>A | Intron (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99272529; called by muse, mutect2
- SNORD116-18 | n.84C>A | RNA (SNP) | VAF 17/215 reads (8%) | called by muse, mutect2
